Somatic mutation profile of tumor specimen TARGET-10-PANWKM-09A (aliquot TARGET-10-PANWKM-09A-01D) from TARGET case TARGET-10-PANWKM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (684 days).
Specimen TARGET-10-PANWKM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6169dec-fd73-4e71-ba5f-6ad21f74f803.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWKM-10A (Blood Derived Normal), aliquot TARGET-10-PANWKM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc6800c6-54ff-4aa6-8312-199ddd9c3f4d

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MAP2 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1369143450, COSV52282887; called by muse, mutect2
- PTCHD4 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.642); catalogued as rs528776718, COSV59778280, COSV59779193; called by muse, mutect2
- STYXL2 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs867643169; called by muse, mutect2, varscan2
- ZNF334 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs1324305478; called by muse, mutect2
- CTSA | c.147G>C p.Q49H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.248); called by muse, mutect2
- NSD2 | c.3850C>T p.H1284Y | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO1D | c.2763G>A p.T921= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as rs1270512031; called by muse, mutect2, varscan2
- PLCD1 | c.1458C>G p.L486= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- PTPRR | c.243C>G p.V81= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- SPTAN1 | c.4891-31C>T | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as COSV63986347; called by muse, mutect2, varscan2
